Somatic mutation profile of tumor specimen TCGA-ZH-A8Y6-01A (aliquot TCGA-ZH-A8Y6-01A-11D-A417-09) from TCGA case TCGA-ZH-A8Y6, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 41.0 years (14,976 days).
Specimen TCGA-ZH-A8Y6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e373d49-d197-47a5-8d35-efdcea71e161.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZH-A8Y6-10A (Blood Derived Normal), aliquot TCGA-ZH-A8Y6-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6036ef68-617c-4fe3-9156-15f8b50aa434

The open-access MAF lists 46 somatic variants for this specimen: 24 protein-altering or splice-affecting, 16 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 16, 3'UTR 2, Frame Shift Del 1, 3'Flank 1, 5'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCT | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375600704; called by muse, mutect2, varscan2
- DNASE1L3 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59155316; called by muse, mutect2, varscan2
- F12 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1233536521; called by muse, mutect2, varscan2
- FAM71B | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV57228214; called by muse, mutect2, varscan2
- FBP1 | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV64689146; called by muse, mutect2
- GRB2 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.065); catalogued as rs756413472; called by muse, varscan2
- HEATR6 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV51744588; called by muse, mutect2, varscan2
- LONP2 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as rs764724665; called by muse, mutect2, varscan2
- MYO15A | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs772104371, COSV99231379; called by muse, mutect2, varscan2
- RARA | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54189681, COSV54192824; called by muse, mutect2, varscan2
- SIRPD | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV67546424; called by muse, mutect2, varscan2
- CCK | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- CREB3L1 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GBF1 | c.1554G>A p.M518I (on ENST00000369983 / NM_001377137.1; = p.M517I on NM_004193.3) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IMPG2 | c.3169C>A p.Q1057K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.394); called by muse, mutect2
- KIR3DL3 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- LIPA | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ME1 | c.1218G>C p.L406F | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTR | c.2800C>G p.Q934E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RB1CC1 | c.4315G>C p.E1439Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- RNF213 | c.10195A>G p.I3399V | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA31A1 | c.710del p.P237Hfs*118 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- SPTY2D1 | c.1200G>C p.Q400H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- THAP9 | c.2392T>C p.Y798H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- ANXA6 | c.1806C>G p.L602= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.1962C>T p.V654= | Silent (SNP) | VAF 38/87 reads (44%) | called by muse, varscan2
- CEP250 | c.5313C>T p.L1771= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- DNA2 | c.946C>T p.L316= | Silent (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.1488C>T p.L496= | Silent (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- IRAK2 | c.1227C>T p.L409= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV56529799, COSV56534939; called by muse, mutect2, varscan2
- KMT2E | c.1152C>T p.F384= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV57575876, COSV99996356; called by muse, mutect2, varscan2
- NHLRC1 | c.738C>T p.F246= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1561881781, COSV61481328; ClinVar: likely benign; called by muse, mutect2, varscan2
- NTRK3 | c.447G>T p.T149= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs780466574, COSV58115160, COSV58149208; called by muse, mutect2, varscan2
- ODF1 | c.252A>G p.R84= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- PCNX2 | c.3750C>T p.F1250= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV50803676; called by muse, mutect2, varscan2
- RASSF10 | c.561C>T p.L187= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs1400993533; called by muse, mutect2, varscan2
- RIN2 | c.1608C>T p.F536= (on ENST00000255006 / NM_001242581.1; = p.F487= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs368824899; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC4A10 | c.2523G>A p.R841= (on ENST00000446997 / NM_001354461.2; = p.R811= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- TXNDC16 | c.705G>A p.L235= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs1447931552; called by muse, mutect2, varscan2
- XKR3 | c.213C>T p.I71= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV100509341; called by muse, mutect2, varscan2
- DNAJC11 | c.*1003G>A | 3'UTR (SNP) | VAF 15/37 reads (41%) | catalogued as rs1211448689, COSV50011138; called by muse, mutect2, varscan2
- EHMT1 | chr9:137838423 C>T | 3'Flank (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- KCNC2 | c.*750C>T | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1292C>A | RNA (SNP) | VAF 15/33 reads (45%) | catalogued as COSV59423375; called by muse, mutect2, varscan2
- SKA2 | c.33+173C>A | Intron (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- UBL3 | c.-1G>A | 5'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
